CCDI case PBBYGB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Skin.
https://portal.gdc.cancer.gov/cases/a0b662c4-159f-48e9-b1ba-79035321867a

Demographics
Sex at birth: male; Vital status: Alive.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin of lower limb and hip; Age at diagnosis: 12.6 years (4,608 days).

Biospecimens (3 samples)
- Sample 0DNRTM: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DNRTT: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DNRUR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
